Somatic mutation profile of tumor specimen MMRF_1152_1_BM_CD138pos (aliquot MMRF_1152_1_BM_CD138pos_T2_TSE61_K03194) from MMRF case MMRF_1152, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.0 years (24,476 days).
Specimen MMRF_1152_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c2ebca0-5695-4830-9f1c-bbd2879b36e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1152_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1152_1_PB_Whole_C1_TSE61_K03197; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2b8bb1d-d969-408d-9359-7f2edca90e1e

The open-access MAF lists 175 somatic variants for this specimen: 65 protein-altering or splice-affecting, 22 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, 3'UTR 52, Silent 22, 5'Flank 13, 3'Flank 8, RNA 6, 5'UTR 6, Intron 3, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 10/50 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.227A>C p.E76A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1648A>G p.I550V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as rs1234017934; called by muse, mutect2, varscan2
- ADGRL3 | c.1189G>T p.D397Y (on ENST00000506720 / NM_001322402.2; = p.D329Y on NM_015236.6) | Missense Mutation (SNP) | VAF 78/81 reads (96%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV72273949; called by muse, mutect2, varscan2
- AL592490.1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69427551; called by muse, mutect2, varscan2
- ANKRD24 | c.2842G>A p.A948T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs368240733; called by muse, mutect2, varscan2
- ASTN2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1173826172, COSV57770652, COSV57811297; called by muse, mutect2, varscan2
- C4orf45 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs776268661, COSV71701197; called by muse, mutect2, varscan2
- DMRTA1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.226); catalogued as rs1245209816; called by muse, mutect2, varscan2
- EPHA8 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs202149500, COSV51265787; called by muse, mutect2, varscan2
- GJA8 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.109); catalogued as rs377069862, COSV53790632; called by muse, mutect2, varscan2
- GJC2 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1317955145; called by muse, mutect2, varscan2
- GRIK3 | c.1744G>A p.V582I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.844); catalogued as rs371012951, COSV66136375, COSV66144296; called by muse, mutect2
- H2BC17 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 315/496 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as COSV58152575; called by muse, mutect2, varscan2
- H3C7 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.829); catalogued as rs200676364, COSV55100312; called by muse, mutect2, varscan2
- IFT172 | c.1408A>G p.I470V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.009); catalogued as rs563278243; called by muse, mutect2, varscan2
- MAGEL2 | c.2989G>A p.A997T | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs558186319, COSV100045801; called by muse, mutect2, varscan2
- MAGI3 | c.1362C>T p.G454= | Splice Region (SNP) | VAF 26/34 reads (76%) | catalogued as rs770455774, COSV100288900; called by muse, mutect2, varscan2
- MAP3K15 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 36/37 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs781456790; called by muse, mutect2, varscan2
- MFHAS1 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.869); catalogued as rs778253432; called by muse, mutect2, varscan2
- MS4A15 | c.292G>A p.G98S (on ENST00000405633 / NM_001098835.2; = p.G5S on NM_152717.3) | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as rs1267217331; called by muse, mutect2, varscan2
- PCDHA7 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 40/866 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs1554135772, COSV65343760, COSV65346769; called by muse, mutect2
- POU2F3 | c.909C>A p.N303K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs755492289; called by muse, mutect2, varscan2
- RAI1 | c.3919C>T p.R1307W | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs367703186, COSV55395743; called by muse, mutect2, varscan2
- SF3B4 | c.290A>G p.D97G | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV54963939; called by muse, mutect2, varscan2
- SFTPC | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547252810; called by muse, mutect2, varscan2
- SLC27A6 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs747373761; called by muse, mutect2, varscan2
- TENT5C | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65616200; called by muse, mutect2, varscan2
- THBS1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs773042685; called by muse, mutect2
- ZFYVE16 | c.3610T>C p.Y1204H | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746219273; called by muse, mutect2, varscan2
- AADACL2 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK | c.13202_13204del p.G4401del | In Frame Del (DEL) | VAF 75/502 reads (15%) | called by mutect2, pindel, varscan2
- BCL11B | c.1158C>A p.N386K (on ENST00000357195 / NM_001282237.2; = p.N315K on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CCDC120 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- CDH10 | c.2218G>T p.G740* | Nonsense Mutation (SNP) | VAF 56/91 reads (62%) | called by muse, mutect2, varscan2
- CDH23 | c.5515A>G p.I1839V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTN5 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- CPA4 | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DGKA | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMKN | c.1318A>T p.T440S | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- DPRX | c.188G>A p.W63* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- ENTPD6 | c.1101_1102del p.R367Sfs*91 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | called by pindel, varscan2
- FBXO41 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- GFI1 | c.13T>A p.F5I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GJB7 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.7); called by muse, mutect2
- GLI3 | c.1514A>G p.H505R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPC2 | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2
- HSPA9 | c.1802A>T p.D601V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MCMBP | c.140dup p.W48Vfs*16 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- MRPL24 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAMPT | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCOR2 | c.590A>T p.Q197L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NDST1 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.649); called by muse, mutect2
- NYAP1 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 53/323 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPN6 | c.680T>G p.V227G | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RNF133 | c.589G>C p.V197L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- RUSC1 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SGO2 | c.1448A>T p.D483V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLC50A1 | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2
- STIM2 | c.1550G>T p.R517L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- STK16 | c.58T>C p.Y20H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TONSL | c.239T>C p.M80T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2
- UROC1 | c.1323A>G p.I441M | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZFP82 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ZNF804B | c.2045T>C p.I682T | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT tolerated (0.44); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ACSM2A | c.987C>A p.P329= (on ENST00000219054; = p.P250= on NM_001308169.2) | Silent (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- BRD3 | c.1833C>T p.P611= | Silent (SNP) | VAF 21/157 reads (13%) | catalogued as rs369709520, COSV57702634; called by muse, mutect2, varscan2
- CACNG7 | c.375G>A p.P125= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs766519700, COSV55816649; called by muse, mutect2, varscan2
- COPS8 | c.156T>C p.N52= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- FBLL1 | c.486C>A p.G162= | Silent (SNP) | VAF 39/285 reads (14%) | catalogued as rs955911349; called by muse, mutect2, varscan2
- GAL3ST2 | c.300G>A p.A100= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as rs200308140, COSV51949406; called by muse, mutect2, varscan2
- GEMIN4 | c.3102C>T p.F1034= | Silent (SNP) | VAF 48/79 reads (61%) | called by muse, mutect2, varscan2
- H1-3 | c.408C>T p.A136= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs1210550911; called by muse, mutect2, varscan2
- HMX3 | c.357C>T p.P119= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- KLHDC7A | c.1653C>T p.P551= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs1182436338, COSV68769941; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3645G>A p.A1215= | Silent (SNP) | VAF 37/167 reads (22%) | catalogued as rs371463608; called by muse, mutect2, varscan2
- MMP14 | c.1473G>A p.L491= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- NT5DC2 | c.429A>G p.T143= | Silent (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- PCLO | c.7005A>G p.L2335= | Silent (SNP) | VAF 37/62 reads (60%) | catalogued as COSV100433255; called by muse, mutect2, varscan2
- PCSK6 | c.1290C>T p.I430= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs376147035; called by muse, mutect2, varscan2
- RLIM | c.726T>A p.S242= | Silent (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- SARDH | c.1164C>T p.P388= | Silent (SNP) | VAF 64/223 reads (29%) | catalogued as rs1045244357, COSV100898807; called by muse, mutect2, varscan2
- SPEG | c.951G>A p.G317= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- SRSF8 | c.624T>G p.S208= | Silent (SNP) | VAF 64/167 reads (38%) | called by muse, mutect2, varscan2
- UBE2QL1 | c.345C>T p.V115= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- USP28 | c.2829C>T p.S943= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs775954822, COSV50167393; called by muse, mutect2, varscan2
- VAT1L | c.1122C>A p.G374= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV56828766; called by muse, mutect2
- AC025048.6 | n.519G>T | RNA (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- ADAM12 | c.-138G>A | 5'UTR (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- AGPAT4 | c.348+4483G>A | Intron (SNP) | VAF 13/63 reads (21%) | catalogued as COSV57243253; called by muse, mutect2, varscan2
- ANKRD26P3 | n.2342C>A | RNA (SNP) | VAF 34/66 reads (52%) | called by mutect2, varscan2
- BET1L | c.*1005T>G | 3'UTR (SNP) | VAF 40/248 reads (16%) | called by muse, mutect2, varscan2
- BMP6 | c.*582T>C | 3'UTR (SNP) | VAF 15/107 reads (14%) | catalogued as rs1561801480; called by muse, mutect2, varscan2
- CAMK2B | c.*1545G>A | 3'UTR (SNP) | VAF 28/139 reads (20%) | catalogued as rs184866493; called by muse, mutect2, varscan2
- CCDC81 | c.-204C>T | 5'UTR (SNP) | VAF 8/63 reads (13%) | catalogued as rs1445086940; called by muse, mutect2, varscan2
- CEP57L1 | c.*758T>G | 3'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as rs549141594; called by muse, mutect2
- CLIP3 | c.*118G>A | 3'UTR (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- CSAG1 | c.*118G>T | 3'UTR (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- CXXC1 | c.-273C>T | 5'UTR (SNP) | VAF 37/69 reads (54%) | called by muse, mutect2, varscan2
- CYB561A3 | c.-16+445G>C | Intron (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- DGKB | c.*1562A>C | 3'UTR (SNP) | VAF 75/103 reads (73%) | called by muse, mutect2, varscan2
- DGKB | c.*871G>A | 3'UTR (SNP) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- DPYSL5 | c.*663G>A | 3'UTR (SNP) | VAF 13/40 reads (33%) | catalogued as rs1329114284; called by muse, mutect2, varscan2
- DST-AS1 | n.139+7834del | Intron (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- EXOC6 | c.*979C>T | 3'UTR (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- FGF1 | c.*1295T>C | 3'UTR (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
- GABRA4 | c.*8027T>C | 3'UTR (SNP) | VAF 59/59 reads (100%) | called by muse, mutect2, varscan2
- GALNT13 | c.*1649G>A | 3'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- GET1-SH3BGR | c.*125T>C | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- GNAL | chr18:11882013 G>A | 3'Flank (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- GRIN3A | c.*293C>T | 3'UTR (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- HBEGF | c.*244T>C | 3'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- HCG11 | n.3878C>T | RNA (SNP) | VAF 7/39 reads (18%) | catalogued as rs574635728; called by muse, mutect2, varscan2
- IGHD3-3 | chr14:105918144 G>C | 5'Flank (SNP) | VAF 70/70 reads (100%) | called by muse, varscan2
- IGHD3-3 | chr14:105918181 ins G | 5'Flank (INS) | VAF 48/72 reads (67%) | called by pindel, varscan2
- IGHD3-3 | chr14:105918247 C>G | 5'Flank (SNP) | VAF 63/64 reads (98%) | catalogued as rs565713285; called by muse, varscan2
- IGHD3-3 | chr14:105918331 T>C | 5'Flank (SNP) | VAF 72/78 reads (92%) | called by muse, varscan2
- IGHD3-3 | chr14:105918353 T>C | 5'Flank (SNP) | VAF 68/74 reads (92%) | called by muse, varscan2
- IGHD3-3 | chr14:105918452 C>A | 5'Flank (SNP) | VAF 36/36 reads (100%) | called by muse, varscan2
- IGHD3-3 | chr14:105918511 C>T | 5'Flank (SNP) | VAF 36/36 reads (100%) | catalogued as rs3829445; called by muse, varscan2
- IGHD3-3 | chr14:105918536 T>A | 5'Flank (SNP) | VAF 27/28 reads (96%) | catalogued as rs191957557; called by muse, varscan2
- IGHD3-3 | chr14:105918553 T>C | 5'Flank (SNP) | VAF 12/14 reads (86%) | catalogued as rs1280075348; called by muse, varscan2
- IGHD3-3 | chr14:105918670 G>A | 5'Flank (SNP) | VAF 26/30 reads (87%) | called by muse, varscan2
- IGHD3-3 | chr14:105918737 T>C | 5'Flank (SNP) | VAF 34/34 reads (100%) | catalogued as rs1325203834; called by muse, varscan2
- IGHD3-3 | chr14:105918802 T>C | 5'Flank (SNP) | VAF 52/54 reads (96%) | called by muse, varscan2
- KCNA4 | c.-840A>G | 5'UTR (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- KIAA0895 | c.*1517G>T | 3'UTR (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- KLHL3 | c.*1535G>A | 3'UTR (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- KRTAP4-8 | c.*147G>A | 3'UTR (SNP) | VAF 17/292 reads (6%) | catalogued as rs557553322; called by muse, mutect2
- LINC00906 | n.929G>A | RNA (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- MAML3 | c.*1202G>T | 3'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- MAP2K7 | c.*1192G>A | 3'UTR (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- MEGF6 | c.*273A>G | 3'UTR (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- MIR924HG | n.1922T>C | RNA (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- NELL2 | c.*365C>T | 3'UTR (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- NFATC3 | c.*2213T>A | 3'UTR (SNP) | VAF 27/44 reads (61%) | catalogued as COSV99251470; called by muse, mutect2, varscan2
- NLGN1 | c.-258T>A | 5'UTR (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- NPTX2 | c.*36C>T | 3'UTR (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- NUP58 | c.*2237C>A | 3'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- OR7E91P | n.649A>G | RNA (SNP) | VAF 224/492 reads (46%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | chr9:109948723 C>T | 3'Flank (SNP) | VAF 65/94 reads (69%) | called by muse, mutect2, varscan2
- PAX7 | c.*1795C>T | 3'UTR (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- PLXNA2 | c.*1165G>A | 3'UTR (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- PPARGC1A | c.*2119T>C | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- PPP6R3 | c.*1099_*1100del | 3'UTR (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- PTPRB | chr12:70520011 A>G | 3'Flank (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- PTPRD | c.*519G>T | 3'UTR (SNP) | VAF 15/84 reads (18%) | catalogued as rs1231814153; called by muse, mutect2, varscan2
- PURB | c.*7388A>G | 3'UTR (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- RAD1 | c.*18T>C | 3'UTR (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- RGS6 | c.*1112G>A | 3'UTR (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- SELE | c.*1398A>G | 3'UTR (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- SEPTIN6 | chrX:119617302 A>G | 3'Flank (SNP) | VAF 71/72 reads (99%) | called by muse, mutect2, varscan2
- SEPTIN6 | chrX:119617382 A>G | 3'Flank (SNP) | VAF 57/57 reads (100%) | called by muse, mutect2, varscan2
- SGMS2 | chr4:107914610 A>C | 3'Flank (SNP) | VAF 47/47 reads (100%) | called by muse, mutect2, varscan2
- SHANK2 | chr11:70468037 C>G | 3'Flank (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- SMAD5 | c.*270A>G | 3'UTR (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- SRD5A2 | c.*1050C>T | 3'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- SRPK1 | c.*737G>A | 3'UTR (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- SRSF11 | c.*391C>T | 3'UTR (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*3568A>G | 3'UTR (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- TGFBR1 | c.*331G>T | 3'UTR (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- TIAM2 | chr6:155257410 G>A | 3'Flank (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- TMEM106C | c.*26G>A | 3'UTR (SNP) | VAF 17/79 reads (22%) | catalogued as rs933663945; called by muse, mutect2, varscan2
- TMEM132E | chr17:34576558 T>C | 5'Flank (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- TMEM182 | c.*710T>C | 3'UTR (SNP) | VAF 11/44 reads (25%) | catalogued as rs1453282389; called by muse, mutect2, varscan2
- TMTC4 | c.-45C>T | 5'UTR (SNP) | VAF 20/30 reads (67%) | catalogued as rs768815620; called by muse, mutect2, varscan2
- TSPYL4 | c.*1217C>T | 3'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- VWA5A | c.*95C>T | 3'UTR (SNP) | VAF 61/82 reads (74%) | called by muse, mutect2, varscan2
- WASF1 | c.*202T>C | 3'UTR (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2
- ZNF234 | c.*36A>G | 3'UTR (SNP) | VAF 92/132 reads (70%) | called by muse, mutect2, varscan2
- ZNF426 | c.*33G>C | 3'UTR (SNP) | VAF 167/242 reads (69%) | called by muse, mutect2, varscan2
- ZNF500 | c.*203T>A | 3'UTR (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
- ZNF501 | c.*320T>G | 3'UTR (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- ZNF532 | c.*642G>A | 3'UTR (SNP) | VAF 26/98 reads (27%) | catalogued as rs1032836458; called by muse, mutect2, varscan2
- ZNF99 | c.*255C>T | 3'UTR (SNP) | VAF 97/636 reads (15%) | catalogued as rs1476755415, COSV101233987, COSV68055304, COSV68055875; called by muse, mutect2, varscan2
